MMRF case MMRF_1188 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5178a832-10df-4dc2-8c8d-a8a0e7309a77

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 76 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 76.3 years (27,869 days); ISS stage: III; Days to last known disease status: 1,583 days (4.3 years); Days to last follow up: 1,583 days (4.3 years).
   Treatment given: Therapeutic agents: Bendamustine; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 234 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 800 days (2.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,198 days (3.3 years); Days to treatment end: 1,331 days (3.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,303 days (3.6 years).
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,479 days (4.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27 (ECOG 2): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.2 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 21.1 g/L; Immunoglobulin M 0.62 g/L; Beta 2 Microglobulin 6.62 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 3.03 mmol/L; Albumin 41 g/L; Total Protein 8.4 g/dL; Glucose 3.58 mmol/L.
- Day 65 (ECOG 2): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.7 mg/dL; Immunoglobulin G 9.52 g/L; Immunoglobulin A 2.66 g/L; Beta 2 Microglobulin 4.44 µg/mL; Lactate Dehydrogenase 9.74 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 33 g/L; Total Protein 6.3 g/dL; Glucose 9.57 mmol/L.
- Day 163 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 6.16 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 4.71 µg/mL; Lactate Dehydrogenase 17.6 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 5.8 g/dL; Glucose 8.69 mmol/L.
- Day 226 (ECOG 2): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 3.79 µg/mL; Lactate Dehydrogenase 12.6 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.08 mmol/L; Albumin 31 g/L; Total Protein 5.9 g/dL; Glucose 6.55 mmol/L.
- Day 338 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 6.77 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.82 µg/mL; Lactate Dehydrogenase 7.72 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 5.06 mmol/L.
- Day 422 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 8.91 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 4.07 µg/mL; Lactate Dehydrogenase 8.69 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 4.57 mmol/L.
- Day 514 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.68 g/L; Beta 2 Microglobulin 4.66 µg/mL; Lactate Dehydrogenase 8.27 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 4.9 mmol/L.
- Day 604 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.87 g/L; Beta 2 Microglobulin 4.86 µg/mL; Lactate Dehydrogenase 9.35 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 4.18 mmol/L.
- Day 688 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.61 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 1.53 g/L; Immunoglobulin M 1.13 g/L; Beta 2 Microglobulin 4.2 µg/mL; Lactate Dehydrogenase 8.74 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 127 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7.6 g/dL; Glucose 4.84 mmol/L.
- Day 772 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.75 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 1.12 g/L; Beta 2 Microglobulin 4.07 µg/mL; Lactate Dehydrogenase 10.2 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 4.13 mmol/L.
- Day 828 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.34 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 2.05 g/L; Immunoglobulin M 0.97 g/L; Beta 2 Microglobulin 4.75 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 52 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 5.17 mmol/L.
- Day 1,073 (ECOG 1): Hemoglobin 7.75 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 138 ×10⁹/L.
- Day 1,129 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.25 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 3.23 g/L; Immunoglobulin M 1.47 g/L; Beta 2 Microglobulin 6.13 µg/mL.
- Day 1,240 (ECOG 3): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 44.9 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 3.64 g/L; Immunoglobulin M 0.93 g/L; Beta 2 Microglobulin 7.7 µg/mL; Hemoglobin 7.19 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.05 mmol/L; Albumin 32 g/L; Total Protein 6.7 g/dL; Glucose 9.79 mmol/L.
- Day 1,331 (ECOG 3): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.3 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 3.42 g/L; Immunoglobulin M 0.8 g/L; Hemoglobin 5.02 mmol/L; Leukocytes 10.9 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 233 µmol/L; Blood Urea Nitrogen 19.3 mmol/L; Calcium 1.88 mmol/L; Albumin 29 g/L; Total Protein 6.1 g/dL; Glucose 4.95 mmol/L.
- Day 1,493 (ECOG 2): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.97 mg/dL; Immunoglobulin G 8.3 g/L; Immunoglobulin A 6.75 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 9.35 µg/mL; Lactate Dehydrogenase 11.2 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 21.1 ×10⁹/L; Absolute Neutrophil 15.5 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 192 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.6 g/dL; Glucose 6.99 mmol/L.
- Day 1,583 (ECOG 2): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.36 mg/dL; Immunoglobulin G 5.95 g/L; Immunoglobulin A 5.3 g/L; Immunoglobulin M 0.375 g/L; Beta 2 Microglobulin 7.99 µg/mL; Hemoglobin 6.2 mmol/L; Leukocytes 14.3 ×10⁹/L; Absolute Neutrophil 8.7 ×10⁹/L; Platelets 84 ×10⁹/L; Creatinine 210 µmol/L; Blood Urea Nitrogen 19.6 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day -27: Weight: 78 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1188_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_1188_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
